Somatic mutation profile of tumor specimen TCGA-XU-AAXW-01A (aliquot TCGA-XU-AAXW-01A-11D-A428-09) from TCGA case TCGA-XU-AAXW, project TCGA-THYM (Thymoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Thymoma, type B2, malignant; Tissue or organ of origin: Thymus; Age at diagnosis: 39.4 years (14,408 days).
Specimen TCGA-XU-AAXW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9e2bd332-5d97-41db-be1b-808985a14713.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XU-AAXW-10A (Blood Derived Normal), aliquot TCGA-XU-AAXW-10A-01D-A42B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6591a68a-e467-4b71-852f-c01b6e2cdb28

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SELENOV | c.872C>T p.P291L | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs998823659; called by muse, mutect2
- CACNA1E | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- WEE2 | c.563G>T p.G188V | Missense Mutation (SNP) | VAF 4/57 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.147); called by muse, mutect2
